MMRF case MMRF_2819 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/742c1099-69b6-451b-9f47-74b787653696

Demographics
Sex at birth: male; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.5 years (20,652 days); ISS stage: II; Days to last known disease status: 245 days; Days to last follow up: 245 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 247 days; Days to treatment end: 247 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -12, day 245.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 3.06 mg/dL.
- Platelets 196 ×10⁹/L.
- Creatinine 79.6 µmol/L.
- Hemoglobin 6.32 mmol/L.
- Calcium 2.33 mmol/L.
- Lactate Dehydrogenase 6.05 µkat/L.
- M Protein 5.5 g/dL.
- Beta 2 Microglobulin 3 µg/mL.
- Absolute Neutrophil 2.78 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.33 mg/dL.
- Albumin 30 g/L.

Other clinical attributes
- Day -12: Weight: 110 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2819_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2819_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
